Gene-level copy-number profile of tumor specimen TCGA-EE-A2A1-06A from TCGA case TCGA-EE-A2A1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.3 years (18,742 days).
Specimen TCGA-EE-A2A1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.3b7d31db-eef6-4374-92d9-dfd40fbe39ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2A1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccc6773e-fec2-4199-865f-b92dbafd298c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 4,843; copy number 2: 40,770; copy number 3: 9,393; copy number 4: 3,349; copy number 6: 1,458.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2A1-06A-11D-A191-01): tumor purity 0.33, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,458 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:87,250–64,313,132, 1,458 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,463. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
